Somatic mutation profile of tumor specimen ALCH-AF3D-TTP1-A (aliquot ALCH-AF3D-TTP1-A-1-0-D-A657-36) from ALCHEMIST case ALCH-AF3D, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.4 years (23,143 days).
Specimen ALCH-AF3D-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fad493c3-f35d-48fe-9cd7-cfa4a9b8a987.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AF3D-NB1-A (Blood Derived Normal), aliquot ALCH-AF3D-NB1-A-1-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f7b0b66-832e-4387-9e1a-30feae68cd26

The open-access MAF lists 21 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 5, Nonsense Mutation 2, Splice Region 2, Intron 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PDLIM7 | c.1084G>A p.V362M | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.374); catalogued as rs1303799262, COSV63080588; called by muse, varscan2
- REEP5 | c.119-5C>T | Splice Region (SNP) | VAF 9/207 reads (4%) | catalogued as rs1410176646, COSV54843495; called by muse, mutect2
- SPTBN1 | c.2891G>C p.C964S | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.759); catalogued as COSV61691687; called by muse, mutect2
- TMEM232 | c.1804G>T p.E602* | Nonsense Mutation (SNP) | VAF 34/392 reads (9%) | catalogued as COSV70272139; called by muse, mutect2
- TP53 | c.871A>T p.K291* | Nonsense Mutation (SNP) | VAF 42/416 reads (10%) | catalogued as COSV52761043, COSV52809147, COSV52984891; called by muse, mutect2
- ERCC1 | c.402G>C p.Q134H | Missense Mutation (SNP) | VAF 10/276 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2
- F5 | c.1893C>G p.F631L | Missense Mutation (SNP) | VAF 75/541 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- FAM193A | c.1173dup p.D392Rfs*13 | Frame Shift Ins (INS) | VAF 10/68 reads (15%) | called by mutect2, pindel, varscan2
- HECA | c.836T>G p.I279S | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PIN4 | c.296A>T p.D99V (on ENST00000664196; = p.D74V on NM_006223.4) | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PLPP3 | c.68A>T p.N23I | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- RTN4R | c.1163C>G p.P388R | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, varscan2
- SLC38A4 | c.1528C>A p.P510T | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- UBLCP1 | c.928A>C p.R310= | Splice Region (SNP) | VAF 23/141 reads (16%) | called by muse, mutect2, varscan2
- CLIP4 | c.591C>T p.N197= | Silent (SNP) | VAF 40/329 reads (12%) | called by muse, mutect2, varscan2
- CRACD | c.858G>A p.A286= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as rs1024424470, COSV51725879; called by mutect2, varscan2
- ITGAM | c.933C>T p.H311= | Silent (SNP) | VAF 20/184 reads (11%) | catalogued as rs757822936, COSV54937034; called by muse, mutect2, varscan2
- RGL2 | c.756C>G p.T252= | Silent (SNP) | VAF 12/172 reads (7%) | catalogued as rs1301902181; called by muse, mutect2
- TLE6 | c.1335C>T p.C445= (on ENST00000246112 / NM_001143986.2; = p.C322= on NM_024760.3) | Silent (SNP) | VAF 24/141 reads (17%) | catalogued as rs1347609712, COSV99858460; called by muse, mutect2, varscan2
- NR2C1 | c.1531+39del | Intron (DEL) | VAF 9/89 reads (10%) | catalogued as rs1190213192; called by mutect2, pindel
- SARAF | c.104-4169T>G | Intron (SNP) | VAF 27/242 reads (11%) | called by muse, varscan2
